MMRF case MMRF_1618 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8dca2518-6012-42be-925e-ae7cd2b713f8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.9 years (20,427 days); ISS stage: I; Days to last known disease status: 1,167 days (3.2 years); Days to last follow up: 1,167 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 86 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 338 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,167.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16 (ECOG 0): M Protein 3.66 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 124 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.245 mg/dL; Immunoglobulin G 46.1 g/L; Immunoglobulin A 0.108 g/L; Immunoglobulin M 0.118 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 4.59 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 9.3 g/dL; Glucose 5.34 mmol/L.
- Day 93 (ECOG 0): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.315 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.593 mg/dL; Immunoglobulin G 8.42 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.326 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.08 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 5.45 mmol/L.
- Day 135 (ECOG 1): M Protein 0.141 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.329 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 7.15 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 60 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.34 mmol/L.
- Day 205 (ECOG 1): M Protein 0.0345 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.329 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.224 mg/dL; Immunoglobulin G 5.94 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 48 g/L; Total Protein 6.9 g/dL; Glucose 4.95 mmol/L.
- Day 394 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.284 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.48 mg/dL; Immunoglobulin G 4.31 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.
- Day 574 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.284 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.677 mg/dL; Immunoglobulin G 4.37 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 619 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 4.84 mmol/L.
- Day 756 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 5.23 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 5.23 mmol/L.
- Day 938 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.913 mg/dL; Immunoglobulin G 4.03 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.16 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 3.74 mmol/L.
- Day 1,127 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 4 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 5.06 mmol/L.

Other clinical attributes
- Day -16: Weight: 80 kg; Height: 163 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1618_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -16 days.
- Sample MMRF_1618_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -16 days.
